Gene-level copy-number profile of tumor specimen ALCH-B2V5-TTP1-A from ALCHEMIST case ALCH-B2V5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.5 years (20,622 days).
Specimen ALCH-B2V5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7caeedce-633e-4cde-a1a8-139bcd59f293.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2V5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/1e8db0d1-968c-409c-9c3a-1035d1ce6bc4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 7,304; copy number 2: 46,115; copy number 3: 4,922; copy number 4: 35; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr7:6,855,485–6,880,626, 3 genes: UNC93B2, OR7E136P, OR7E59P.
- chr7:102,293,103–102,293,187, 1 gene (within-gene range 0–2): MIR4285.
- chr9:132,582,606–132,590,252, 1 gene: BARHL1.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr11:12,538,083–12,540,967, 1 gene: AC009806.1.
- chr14:93,934,166–93,976,739, 3 genes: ASB2, AL132642.1, MIR4506.
- chr15:64,739,891–64,825,668, 3 genes: RBPMS2, MIR1272, PIF1.
- chr17:62,260,634–62,275,655, 2 genes (within-gene range 0–2): AC053481.4, TBC1D3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 5 (within-gene range 2–5): TTC34, AC242022.2, AC242022.1.
- chr5:58,491,435–58,503,700, 2 genes, copy number 5: GAPT, AC008814.1.

Autosomal genes at a single copy (total copy number 1): 6,765. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
